Gene-level copy-number profile of tumor specimen TCGA-DX-A6BH-01A from TCGA case TCGA-DX-A6BH, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 34.9 years (12,742 days).
Specimen TCGA-DX-A6BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e793f45a-e1f9-4760-af92-4b2d4118ce92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e2eb259-537f-4aea-a2f6-716d5d6801f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,237; copy number 2: 54,933; copy number 3: 44; copy number 6: 65; copy number 7: 53; copy number 8: 34; copy number 9: 5; copy number 10: 4; copy number 13: 2; copy number 14: 18; copy number 15: 27; copy number 16: 49; copy number 17: 9; copy number 18: 73; copy number 19: 29; copy number 20: 33; copy number 21: 48; copy number 22: 16; copy number 23: 39; copy number 24: 4; copy number 25: 12; copy number 26: 23; copy number 27: 8; copy number 28: 1; copy number 29: 20; copy number 30: 2; copy number 31: 9; copy number 33: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BH-01A-12D-A306-01): tumor purity 0.64, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 603 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,513,377–157,640,301, 4 genes, copy number 7: FCRL5, FCRL4, AL135929.2, AL135929.1.
- chr1:165,210,627–165,213,090, 1 gene, copy number 8: LMX1A-AS2.
- chr1:166,165,911–167,220,512, 23 genes, copy number 6–24 (within-gene range 2–24): AL596087.2, AL596087.1, AL583804.1, FMO7P, LINC01675, FMO8P, FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2.
- chr1:169,511,951–172,418,466, 65 genes, copy number 16–25 (within-gene range 2–25) (broad region; genes not listed).
- chr1:175,877,343–176,207,286, 6 genes, copy number 20: LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1.
- chr1:176,217,541–176,244,029, 3 genes, copy number 20: U7, AL359265.2, RNU2-12P.
- chr6:41,302,466–41,350,889, 3 genes, copy number 20 (within-gene range 2–20): RNU6-643P, AL672212.1, NCR2.
- chr6:41,546,426–42,217,861, 30 genes, copy number 13–26 (within-gene range 2–26): FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10.
- chr6:47,656,436–47,722,021, 3 genes, copy number 23 (within-gene range 10–23): ADGRF2, ADGRF4, RN7SKP116.
- chr6:47,781,982–48,214,794, 6 genes, copy number 22 (within-gene range 3–22): OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:68,223,667–68,576,191, 3 genes, copy number 19 (within-gene range 2–19): AL593844.1, LINC02549, AL606923.2.
- chr6:81,844,602–82,169,391, 2 genes, copy number 30 (within-gene range 2–30): LINC02542, AL360157.1.
- chr6:120,462,511–124,825,640, 43 genes, copy number 7–20 (within-gene range 2–20): AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1.
- chr6:133,240,598–134,133,868, 16 genes, copy number 8 (within-gene range 2–8): EYA4, AL024497.1, AL024497.2, TARID, HSPE1P21, AL450270.1, FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P.
- chr6:137,730,170–139,291,998, 31 genes, copy number 21 (within-gene range 2–21): LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB.
- chr6:139,338,018–139,474,658, 3 genes, copy number 21 (within-gene range 2–21): AL592429.1, CITED2, LINC01625.
- chr6:142,526,455–148,137,404, 77 genes, copy number 8–31 (within-gene range 1–31) (broad region; genes not listed).
- chr6:148,478,693–149,112,672, 7 genes, copy number 8: CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1.
- chr6:149,400,262–151,358,559, 65 genes, copy number 6–15 (within-gene range 2–15) (broad region; genes not listed).
- chr6:152,121,684–152,637,801, 5 genes, copy number 7 (within-gene range 2–7): SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11.
- chr7:107,765,467–108,456,717, 8 genes, copy number 18 (within-gene range 1–18): SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM.
- chr7:113,876,777–116,159,896, 19 genes, copy number 9–28 (within-gene range 1–28): PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC.
- chr7:117,710,651–117,883,675, 2 genes, copy number 6 (within-gene range 1–6): CTTNBP2, AC007568.1.
- chr7:122,676,580–123,790,711, 19 genes, copy number 10–21: AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P.
- chr7:124,032,126–124,489,572, 3 genes, copy number 9 (within-gene range 1–9): AC006148.1, AC006148.2, AC004930.1.
- chr7:125,229,579–125,346,197, 4 genes, copy number 26: AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr7:126,378,970–127,253,093, 8 genes, copy number 6 (within-gene range 1–6): AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592.
- chr7:129,225,023–129,757,082, 9 genes, copy number 6–20 (within-gene range 1–20): AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1.
- chr7:129,953,234–130,207,770, 8 genes, copy number 7–16 (within-gene range 1–16): AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2.
- chr12:57,591,174–58,244,865, 39 genes, copy number 18 (within-gene range 1–18): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:64,759,484–64,990,646, 7 genes, copy number 20 (within-gene range 2–20): TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P.
- chr12:67,648,338–68,451,663, 16 genes, copy number 29 (within-gene range 2–29): DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr12:68,746,125–69,610,907, 26 genes, copy number 17–33 (within-gene range 2–33): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10.
- chr12:69,901,918–70,243,379, 1 gene, copy number 21 (within-gene range 2–21): PRANCR.
- chr12:70,366,290–70,543,040, 3 genes, copy number 29 (within-gene range 2–29): KCNMB4, RNU4-65P, AC025569.1.
- chr12:72,087,266–72,670,758, 3 genes, copy number 17 (within-gene range 2–17): TRHDE, TRHDE-AS1, H3P35.
- chr12:74,656,561–75,298,508, 7 genes, copy number 27: AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1.
- chr12:75,600,047–75,698,816, 5 genes, copy number 23: AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr16:13,246,232–13,563,388, 3 genes, copy number 18: U91319.1, AC003009.1, TMF1P1.
- chr16:13,920,154–14,021,077, 6 genes, copy number 7: ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186.

Autosomal genes at a single copy (total copy number 1): 1,856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
